Gene-level copy-number profile of tumor specimen C3N-03029-01 from CPTAC case C3N-03029, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 70.3 years (25,692 days).
Specimen C3N-03029-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f11b67cb-a362-4c63-a9ee-29c2fd65afe5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03029-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/eca15756-307c-4df8-8d02-22007cf93b94

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 513; copy number 1: 723; copy number 2: 20,040; copy number 3: 28,764; copy number 4: 6,050; copy number 5: 571; copy number 6: 1,941; copy number 7: 75; copy number 8: 98; copy number 9: 44; copy number 10: 59; copy number 11: 9; copy number 12: 7; copy number 13: 4; copy number 15: 3; copy number 16: 3.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,898,805–61,911,022, 1 gene: FAM242E.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 302 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,573,801–248,645,278, 6 genes, copy number 12: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35.
- chr5:58,198–473,098, 19 genes, copy number 7: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080.
- chr5:473,236–480,884, 1 gene, copy number 7 (within-gene range 2–7): SLC9A3-AS1.
- chr5:27,217,714–29,217,115, 17 genes, copy number 7–13: PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3.
- chr5:29,600,676–29,796,268, 2 genes, copy number 10: UBL5P1, AC108082.1.
- chr9:24,542,952–24,905,735, 3 genes, copy number 7: IZUMO3, AL353811.1, RMRPP5.
- chr9:27,829,276–27,844,481, 1 gene, copy number 9: AL360014.1.
- chr9:30,388,935–30,832,225, 7 genes, copy number 7: LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2.
- chr9:31,505,946–31,506,615, 1 gene, copy number 9: MTCO3P30.
- chr9:60,914,407–61,866,965, 21 genes, copy number 9: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2, RN7SL722P, AL391987.2, AL391987.1, AL391987.4.
- chr9:63,581,254–64,082,534, 15 genes, copy number 7: AL591438.1, AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3, CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP, AL163540.1, U6.
- chr9:102,055,252–103,429,892, 10 genes, copy number 7–8: ARL2BPP7, RNU6-329P, AL442644.1, LINC00587, ZYG11AP1, AL365396.1, CYLC2, AL589823.1, LINC01492, AL390962.1.
- chr9:117,180,628–117,181,200, 2 genes, copy number 7 (within-gene range 2–7): RPL10P3, SNORA70C.
- chr9:120,600,811–120,842,951, 6 genes, copy number 10 (within-gene range 2–10): MEGF9, AHCYP2, FBXW2, B3GNT10, AL161911.1, PSMD5.
- chr9:121,821,928–124,948,492, 77 genes, copy number 8–10 (within-gene range 2–10) (broad region; genes not listed).
- chr9:126,516,417–126,701,032, 6 genes, copy number 7: AL356309.2, AL356309.3, AL356309.1, AL161908.1, LMX1B, AL161908.2.
- chr16:47,965,620–48,363,122, 8 genes, copy number 8 (within-gene range 3–8): LINC02134, AC096996.1, ABCC12, AC096996.2, ABCC11, LONP2, UBA52P8, AC023818.1.
- chr16:69,355,567–69,408,571, 1 gene, copy number 8 (within-gene range 3–8): TERF2.
- chr16:80,040,662–80,167,577, 2 genes, copy number 7 (within-gene range 2–7): AC092130.1, AC022166.1.
- chr20:2,075,555–2,177,038, 3 genes, copy number 9: RPL7P2, STK35, AL359916.1.
- chr20:5,532,878–5,950,558, 9 genes, copy number 11: RPS18P1, AL109935.1, GPCPD1, EIF4EP1, SHLD1, RNU1-55P, CHGB, KANK1P1, TRMT6.
- chr22:19,179,473–19,291,719, 5 genes, copy number 10: CLTCL1, AC000072.1, AC000081.1, AC000081.2, KRT18P62.
- chr22:31,051,630–31,120,069, 6 genes, copy number 8: AC005005.4, RN7SL633P, SMTN, AC005005.3, SELENOM, AC005005.2.
- chr22:33,704,786–33,704,922, 2 genes, copy number 9 (within-gene range 2–9): SNORA50B, Z69713.1.
- chr22:38,734,725–38,794,143, 1 gene, copy number 8 (within-gene range 6–8): SUN2.
- chr22:38,778,508–38,998,209, 7 genes, copy number 8–16: DNAL4, NPTXR, CBX6, AL022318.1, APOBEC3A, APOBEC3B, APOBEC3B-AS1.
- chr22:40,951,347–41,240,931, 14 genes, copy number 9: RBX1, Y_RNA, AL080243.2, Y_RNA, AL080243.1, MIR1281, EP300, RNU6-375P, AL035658.1, EP300-AS1, LRRC37A14P, L3MBTL2, L3MBTL2-AS1, CHADL.
- chr22:41,833,079–42,432,403, 29 genes, copy number 10 (within-gene range 2–10): SREBF2, MIR33A, SHISA8, TNFRSF13C, MIR378I, CENPM, LINC00634, SEPTIN3, Z99716.1, WBP2NL, SLC25A5P1, NAGA, PHETA2, SNORD13P1, SMDT1, NDUFA6, AL021878.4, NDUFA6-DT, OLA1P1, CYP2D6, AC254562.1, AC254562.2, AC254562.3, CYP2D7, CYP2D8P, TCF20, OGFRP1, LINC01315, NFAM1.
- chr22:42,617,840–43,187,134, 17 genes, copy number 8: CYB5R3, ATP5MGL, A4GALT, Y_RNA, RPL5P34, GOLGA2P4, AL049757.1, ARFGAP3, PACSIN2, AL049758.1, TTLL1-AS1, TTLL1, AL022237.1, BIK, MCAT, TSPO, TTLL12.
- chr22:43,400,331–43,513,727, 3 genes, copy number 15: LINC01639, MPPED1, BX546033.1.
- chr22:44,752,558–44,862,788, 1 gene, copy number 12 (within-gene range 2–12): ARHGAP8.

Autosomal genes at a single copy (total copy number 1): 723. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
